Somatic mutation profile of tumor specimen TCGA-66-2795-01A (aliquot TCGA-66-2795-01A-02D-0983-08) from TCGA case TCGA-66-2795, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68.2 years (24,897 days).
Specimen TCGA-66-2795-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acf94f19-47cf-4d52-8237-fc9006d9303c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2795-11A (Solid Tissue Normal), aliquot TCGA-66-2795-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5c80cad-1c3a-4c6b-ad89-c718299cb622

The open-access MAF lists 324 somatic variants for this specimen: 246 protein-altering or splice-affecting, 71 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 214, Silent 71, Nonsense Mutation 16, Frame Shift Del 8, RNA 4, Splice Site 3, Splice Region 2, Translation Start Site 1, 3'UTR 1, 5'Flank 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC2 | c.3847C>A p.P1283T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV64988878; called by muse, mutect2, varscan2
- ABI3BP | c.1726G>T p.A576S | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV52538096; called by muse, mutect2, varscan2
- AC100868.1 | c.895T>G p.F299V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51850885; called by muse, mutect2, varscan2
- ACVR2A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV54029894; called by muse, mutect2, varscan2
- ADAD1 | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV56647786; called by muse, mutect2, varscan2
- ADAMTS9 | c.1349G>T p.C450F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55792181; called by muse, mutect2, varscan2
- ADRB1 | c.498C>A p.Y166* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV65168389; called by muse, mutect2, varscan2
- AFF4 | c.1073G>C p.G358A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as COSV54800404; called by muse, mutect2, varscan2
- AGBL2 | c.1259G>T p.C420F | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs762260012, COSV54096017; called by muse, mutect2, varscan2
- AKAP1 | c.1237G>T p.A413S | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV58473390; called by muse, mutect2, varscan2
- AKAP3 | c.2322A>T p.Q774H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57421494; called by muse, mutect2, varscan2
- ALG2 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV53061067; called by muse, mutect2, varscan2
- AMY2B | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 91/200 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV63717347; called by muse, mutect2, varscan2
- ANO3 | c.1382C>A p.A461D | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56808802; called by muse, mutect2, varscan2
- ARID1B | c.4701G>T p.M1567I | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as COSV51683547; called by muse, varscan2
- AS3MT | c.709A>T p.T237S | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV54919391; called by muse, mutect2, varscan2
- ATP11B | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441413082, COSV60033955; called by muse, mutect2, varscan2
- ATP8A1 | c.2213A>T p.N738I | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV52550002; called by muse, mutect2, varscan2
- ATP8B2 | c.3631A>T p.S1211C (on ENST00000672630; = p.S1178C on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV63834224; called by muse, mutect2, varscan2
- BCL11A | c.2327G>T p.S776I (on ENST00000335712 / NM_001365609.1; = p.S810I on NM_022893.4) | Missense Mutation (SNP) | VAF 236/300 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV59638491; called by muse, mutect2, varscan2
- BFSP2 | c.83G>T p.R28M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as rs1202907650, COSV100183660; called by muse, mutect2, varscan2
- CACNA2D1 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs79543314, COSV62373469, COSV62394715; called by muse, varscan2
- CCDC141 | c.3157C>A p.Q1053K | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55384025; called by muse, mutect2, varscan2
- CCDC68 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs773758990, COSV61605029; called by muse, mutect2, varscan2
- CCL7 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV52337825; called by muse, mutect2, varscan2
- CCR5 | c.774C>A p.N258K | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as COSV52753216; called by muse, mutect2, varscan2
- CDC42BPB | c.3193G>T p.V1065L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV63474334, COSV63477192; called by muse, mutect2, varscan2
- CDH9 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV50300303; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2208G>C p.M736I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV62578030; called by muse, mutect2
- CECR2 | c.1856G>A p.R619Q (on ENST00000342247 / NM_001290047.2; = p.R436Q on NM_001290046.1) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs761960139, COSV52841246; called by muse, mutect2, varscan2
- CENPB | c.230T>A p.L77H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60150453; called by muse, mutect2, varscan2
- CHRNA3 | c.789C>A p.F263L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV58777148; called by muse, mutect2, varscan2
- CIAPIN1 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.035); catalogued as COSV67953716; called by muse, mutect2, varscan2
- CLSTN2 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 24/112 reads (21%) | catalogued as COSV71723733; called by muse, mutect2, varscan2
- CNBD1 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV72976779; called by muse, mutect2, varscan2
- CNOT7 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs1453783166, COSV63517936; called by muse, mutect2, varscan2
- COL1A2 | c.3666C>G p.D1222E | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51967354; called by muse, mutect2, varscan2
- COL4A1 | c.3884G>A p.G1295D | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.999); catalogued as COSV65431861; called by muse, mutect2, varscan2
- COL4A2 | c.242C>A p.P81Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV64635334; called by muse, mutect2, varscan2
- COL6A3 | c.7757T>C p.V2586A | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs765245863, COSV55100454; called by muse, mutect2, varscan2
- COP1 | c.483T>A p.H161Q | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.257); catalogued as COSV100443026; called by muse, mutect2, varscan2
- CPA3 | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1396524808, COSV56047769; called by muse, mutect2, varscan2
- CPT1A | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV55761984; called by mutect2, varscan2
- CPZ | c.746G>A p.G249D (on ENST00000360986 / NM_001014447.3; = p.G238D on NM_003652.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59926583; called by muse, mutect2, varscan2
- CREBBP | c.1847C>G p.P616R | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52143307; called by muse, mutect2, varscan2
- CRYBG3 | c.6767G>T p.G2256V | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV51716805; called by muse, mutect2, varscan2
- CSF2RB | c.2420C>T p.S807F | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV53261484; called by muse, mutect2, varscan2
- CSMD3 | c.5338A>T p.K1780* (on ENST00000297405 / NM_001363185.1; = p.K1676* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as COSV52339936; called by muse, mutect2, varscan2
- CSMD3 | c.2611G>A p.E871K (on ENST00000297405 / NM_001363185.1; = p.E767K on NM_052900.3) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); catalogued as rs753251128, COSV52327011; called by muse, mutect2, varscan2
- CSPG4 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs556484915, COSV57902070; called by muse, mutect2, varscan2
- CYP2A7 | c.1152C>A p.F384L | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52499164, COSV52507331; called by muse, mutect2, varscan2
- DARS2 | c.700G>T p.G234* | Nonsense Mutation (SNP) | VAF 20/357 reads (6%) | catalogued as COSV53409558; called by muse, mutect2
- DBR1 | c.1407G>T p.R469S | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.091); catalogued as COSV53431389; called by muse, mutect2, varscan2
- DGKI | c.2349G>C p.E783D | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV55979708; called by muse, mutect2, varscan2
- DISP2 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs746202282, COSV51146918; called by mutect2, varscan2
- DLG2 | c.2129C>G p.P710R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54690573; called by muse, mutect2, varscan2
- DLG2 | c.1023C>T p.T341= | Splice Region (SNP) | VAF 24/84 reads (29%) | catalogued as COSV54690599; called by muse, mutect2, varscan2
- DOCK3 | c.1546G>T p.D516Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56553626; called by muse, mutect2, varscan2
- DROSHA | c.911A>C p.E304A | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.048); catalogued as COSV60783775; called by muse, mutect2, varscan2
- DYRK4 | c.537C>A p.F179L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50541884; called by muse, mutect2, varscan2
- DZIP3 | c.2590-2A>T p.X864_splice | Splice Site (SNP) | VAF 29/137 reads (21%) | catalogued as COSV100847712; called by muse, mutect2, varscan2
- ELOA2 | c.702A>T p.K234N | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV55309881; called by muse, mutect2, varscan2
- ENPP2 | c.1561C>T p.P521S (on ENST00000075322 / NM_001040092.3; = p.P573S on NM_006209.5) | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs752537154, COSV50043427; called by muse, mutect2, varscan2
- ERCC6L2 | c.674C>G p.T225S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV56634703; called by muse, mutect2, varscan2
- FADS2 | c.827C>G p.P276R | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53902989; called by muse, mutect2, varscan2
- FAM114A2 | c.801C>G p.I267M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV61078909; called by muse, mutect2, varscan2
- FAM47C | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV63730944; called by muse, mutect2, varscan2
- FBP2 | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV64695956; called by muse, mutect2, varscan2
- FBXL20 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52904922; called by muse, mutect2, varscan2
- FBXW11 | c.1283G>C p.W428S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51614367; called by muse, mutect2, varscan2
- FKBP1B | c.40A>G p.R14G | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV66768393; called by muse, mutect2, varscan2
- FRAS1 | c.8494G>C p.A2832P | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs369335635, COSV53654208; called by muse, mutect2, varscan2
- FSCB | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV61219755; called by muse, mutect2, varscan2
- GALNT14 | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs202186542, COSV61107393, COSV61111950; called by muse, mutect2, varscan2
- GALNT17 | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61146014; called by muse, mutect2, varscan2
- GLRA2 | c.1071G>T p.R357S | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.966); catalogued as COSV54348365; called by muse, mutect2, varscan2
- GNPAT | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100791590; called by muse, mutect2, varscan2
- GPR141 | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57733822, COSV57734309; called by muse, mutect2, varscan2
- GPR158 | c.2132C>A p.P711Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66284627; called by muse, mutect2, varscan2
- GPR65 | c.635A>T p.H212L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.038); catalogued as COSV50864692; called by muse, mutect2, varscan2
- GRIK3 | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); catalogued as COSV66147945; called by muse, mutect2, varscan2
- GRIN2A | c.2276C>A p.T759N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV58058805; called by muse, mutect2, varscan2
- HCN1 | c.1631T>A p.L544Q | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57540586; called by muse, mutect2, varscan2
- HEPHL1 | c.871T>A p.S291T | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.345); catalogued as COSV104410432, COSV59897276; called by muse, mutect2, varscan2
- HIP1 | c.3038G>T p.G1013V | Missense Mutation (SNP) | VAF 108/372 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61192117; called by muse, mutect2, varscan2
- HOXB9 | c.477A>C p.K159N | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV60817903; called by muse, varscan2
- IGSF10 | c.5564C>A p.T1855N | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as COSV56792812; called by muse, mutect2, varscan2
- IPO11 | c.2836G>A p.E946K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV57583739; called by muse, mutect2, varscan2
- IRS1 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs147944503; called by muse, mutect2, varscan2
- KATNIP | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV55193288; called by muse, mutect2, varscan2
- KCNC2 | c.1279G>T p.G427W | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54362845, COSV54381620; called by muse, varscan2
- KCND2 | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV58580079; called by muse, mutect2, varscan2
- KCND3 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV56190889; called by muse, mutect2, varscan2
- KCNG4 | c.123C>A p.Y41* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as rs371009755; called by muse, mutect2, varscan2
- KCNH7 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV59812299, COSV59816266; called by muse, mutect2, varscan2
- KCNJ2 | c.524T>C p.I175T | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV54664247; called by muse, mutect2, varscan2
- KCNK1 | c.489G>T p.R163S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV64036734; called by muse, mutect2, varscan2
- KCNK18 | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV57971628, COSV57973514; called by muse, mutect2, varscan2
- KDM6A | c.2702G>A p.R901K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.989); catalogued as COSV100938522, COSV65037143, COSV65039959; called by muse, mutect2, varscan2
- KIF2B | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV52136324; called by muse, mutect2, varscan2
- KIF2B | c.628C>G p.Q210E | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52136335; called by muse, mutect2, varscan2
- KLHDC7A | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0.048); catalogued as rs746757189, COSV68769178; called by muse, mutect2, varscan2
- KLHL1 | c.163C>G p.R55G | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.931); catalogued as rs1375251777, COSV64785963; called by muse, mutect2, varscan2
- KLHL32 | c.1163G>T p.R388L | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65110747; called by muse, mutect2, varscan2
- KMO | c.1230G>T p.E410D | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV59367805; called by muse, mutect2, varscan2
- LAMB2 | c.1559G>T p.R520L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV59738495; called by muse, mutect2, varscan2
- LGI3 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV60444476; called by muse, mutect2, varscan2
- LILRB1 | c.841C>A p.Q281K (on ENST00000427581; = p.Q245K on NM_006669.6) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61122221; called by muse, varscan2
- LRRN1 | c.519C>G p.H173Q | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60016666; called by muse, mutect2, varscan2
- LYPLA1 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV57607151; called by muse, varscan2
- MAN2C1 | c.2194G>A p.V732I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.078); catalogued as rs1465310358, COSV51249014; called by muse, mutect2, varscan2
- MANBA | c.515A>G p.Q172R | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56971222; called by muse, mutect2, varscan2
- MAPT | c.2419G>A p.G807S (on ENST00000262410 / NM_001377265.1; = p.G415S on NM_005910.5) | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768841567, COSV52240683, COSV52243319; called by muse, varscan2
- MARCHF10 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV60886541; called by muse, mutect2, varscan2
- MBTPS1 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV58572930; called by muse, mutect2, varscan2
- MDN1 | c.4978G>A p.A1660T | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV65531609; called by muse, mutect2, varscan2
- MEIOC | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 41/83 reads (49%) | catalogued as COSV63441684; called by muse, mutect2, varscan2
- MEOX2 | c.165C>A p.N55K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.66); PolyPhen benign (0.026); catalogued as rs1376752653, COSV56295384; called by muse, mutect2, varscan2
- MGAM | c.1996C>A p.P666T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781810423, COSV101527429; called by mutect2, varscan2
- MKI67 | c.7967C>A p.P2656Q | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV64077481; called by muse, mutect2, varscan2
- MMP2 | c.1933C>G p.L645V | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.027); catalogued as COSV50900632; called by muse, mutect2, varscan2
- MRC2 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV57645223; called by muse, mutect2, varscan2
- MUC16 | c.24404C>A p.A8135D | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.864); catalogued as rs201103908, COSV67499081; called by muse, mutect2, varscan2
- MUC16 | c.23471A>G p.E7824G | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV67499093; called by muse, mutect2, varscan2
- MYH2 | c.1919A>G p.K640R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV55450229; called by muse, mutect2, varscan2
- MYH7B | c.2501C>A p.T834K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99482569; called by muse, varscan2
- NCAM2 | c.2453C>A p.T818N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV99522318; called by muse, mutect2, varscan2
- NOTCH1 | c.3225G>A p.W1075* | Nonsense Mutation (SNP) | VAF 17/113 reads (15%) | catalogued as COSV53100468; called by muse, mutect2, varscan2
- NXPH2 | c.111A>T p.K37N | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV55647446; called by muse, mutect2, varscan2
- OBP2A | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV59793749; called by muse, mutect2, varscan2
- OR10G9 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.362); catalogued as rs1382556018, COSV66686951; called by muse, mutect2, varscan2
- OR10R2 | c.719G>C p.C240S | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV63768430, COSV63769659; called by muse, mutect2, varscan2
- OR2M3 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 79/210 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as COSV71758858, COSV71759331; called by muse, varscan2
- OR4C12 | c.773G>C p.R258P | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58859946, COSV58861260; called by muse, mutect2, varscan2
- OR4N2 | c.312G>C p.L104F | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.452); catalogued as COSV60055565; called by muse, mutect2, varscan2
- OR51S1 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV59060469; called by muse, mutect2, varscan2
- OR5K1 | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.919); catalogued as COSV60305497; called by muse, mutect2, varscan2
- OR6C70 | c.385C>A p.R129S | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV59245531; called by muse, mutect2, varscan2
- OR8S1 | c.909C>G p.D303E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV59601011; called by muse, mutect2, varscan2
- OTOF | c.891C>G p.Y297* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV55522786; called by muse, mutect2, varscan2
- PARP6 | c.441T>A p.N147K | Missense Mutation (SNP) | VAF 126/366 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV53005442; called by muse, mutect2, varscan2
- PARVB | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100114578, COSV58688033, COSV58692157; called by muse, mutect2, varscan2
- PCDH11X | c.110A>T p.N37I | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53510767; called by muse, mutect2, varscan2
- PCDHA4 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.055); catalogued as rs782208317, COSV63539124; called by muse, mutect2, varscan2
- PCDHB13 | c.2314C>A p.P772T | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as COSV53401690, COSV99506790; called by muse, mutect2, varscan2
- PCDHGA5 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54048128; called by muse, mutect2, varscan2
- PCDHGB1 | c.2194G>A p.G732R | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV54048117; called by muse, mutect2, varscan2
- PCLO | c.2657G>T p.G886V | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV61673230; called by muse, mutect2, varscan2
- PDE4DIP | c.3338A>T p.H1113L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.175); catalogued as COSV57733010; called by mutect2, varscan2
- PLCL1 | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as rs773785512, COSV70881419; called by muse, mutect2, varscan2
- PLG | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51986927; called by muse, mutect2, varscan2
- PPP1CA | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); catalogued as COSV56705558; called by muse, mutect2, varscan2
- PRICKLE1 | c.260A>T p.Q87L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV61547378; called by muse, mutect2, varscan2
- PRSS54 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1271464222, COSV54689968; called by muse, mutect2
- RAB3GAP2 | c.1802G>A p.S601N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62787663; called by muse, mutect2, varscan2
- RALGAPA2 | c.3728G>A p.S1243N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV52513258; called by muse, mutect2, varscan2
- RASSF4 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.448); catalogued as COSV58489302; called by muse, mutect2, varscan2
- REM1 | c.623A>T p.E208V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52430402; called by muse, mutect2, varscan2
- RETREG2 | c.763C>T p.H255Y | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as rs985520541, COSV56089132; called by muse, mutect2, varscan2
- REV1 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs1163683813, COSV51491169; called by muse, mutect2, varscan2
- RGS18 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV66510293; called by muse, mutect2, varscan2
- RGS7 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.967); catalogued as rs751557145, COSV58550062, COSV58557354; called by muse, mutect2, varscan2
- RPTN | c.1295G>A p.R432K | Missense Mutation (SNP) | VAF 189/1076 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.629); catalogued as rs765402638, COSV60169497; called by muse, mutect2, varscan2
- RSRC1 | c.271G>C p.G91R | Missense Mutation (SNP) | VAF 98/183 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55828026, COSV55840791; called by muse, mutect2, varscan2
- RYR3 | c.10595C>T p.A3532V (on ENST00000389232; = p.A3533V on NM_001036.6) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); catalogued as COSV66810506; called by muse, mutect2, varscan2
- SCN7A | c.2071G>C p.E691Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs775318530, COSV69272619; called by muse, mutect2, varscan2
- SCRN3 | c.481A>G p.R161G | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55810245; called by muse, mutect2, varscan2
- SDK2 | c.5651C>T p.T1884M | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs770844185, COSV66198370; called by mutect2, varscan2
- SEPTIN7 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.943); catalogued as COSV63257359; called by muse, mutect2, varscan2
- SERPINA3 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.569); catalogued as COSV67587331; called by muse, mutect2, varscan2
- SH3PXD2B | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61130864; called by muse, mutect2, varscan2
- SIGLEC8 | c.1033C>A p.L345M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as COSV58476186; called by muse, mutect2, varscan2
- SLC13A2 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58999307; called by muse, mutect2, varscan2
- SLC44A4 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.109); catalogued as COSV57669436; called by muse, mutect2, varscan2
- SLC4A5 | c.992T>A p.L331Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV61033768; called by muse, mutect2, varscan2
- SLITRK5 | c.2645G>T p.C882F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV61526976; called by muse, mutect2, varscan2
- SMARCAD1 | c.665T>A p.F222Y | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62776459; called by muse, mutect2, varscan2
- SMCHD1 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV55270329; called by muse, mutect2, varscan2
- SPCS1 | c.244A>T p.K82* (on ENST00000233025; = p.K15* on NM_014041.5) | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV51778263; called by muse, mutect2, varscan2
- SPTA1 | c.3221G>A p.R1074H | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs551084590, COSV63755314; called by muse, mutect2, varscan2
- SREK1 | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV52335457; called by muse, mutect2, varscan2
- SRSF1 | c.186G>T p.E62D | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as COSV51966701; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2624G>C p.S875T | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV59139405; called by muse, mutect2, varscan2
- SUPT3H | c.733G>C p.D245H (on ENST00000371460 / NM_181356.3; = p.D234H on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60953354; called by muse, mutect2, varscan2
- TAF1 | c.2818G>T p.G940C (on ENST00000373790 / NM_138923.4; = p.G961C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52112302, COSV52127354; called by muse, mutect2, varscan2
- TAF1 | c.2819G>T p.G940V (on ENST00000373790 / NM_138923.4; = p.G961V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52127375; called by muse, mutect2, varscan2
- TASP1 | c.592A>G p.R198G | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV61816406; called by muse, mutect2, varscan2
- TCF20 | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.813); catalogued as rs775188096, COSV59495650; called by muse, mutect2, varscan2
- TCP11 | c.452A>T p.H151L (on ENST00000512012; = p.H89L on NM_018679.5) | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV55136518; called by muse, mutect2, varscan2
- TEX13A | c.565G>T p.G189* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV61186667; called by muse, mutect2, varscan2
- TEX14 | c.4476G>T p.Q1492H (on ENST00000240361 / NM_001201457.2; = p.Q1446H on NM_031272.5) | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53628016; called by muse, mutect2, varscan2
- TFDP1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs754332412, COSV64742403; called by muse, mutect2, varscan2
- THADA | c.4516G>T p.A1506S | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs199689117, COSV57694533; called by muse, varscan2
- THSD7B | c.3122T>A p.L1041Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55744914; called by muse, mutect2
- TMC3 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.547); catalogued as rs199928703, COSV100845829, COSV63924037; called by muse, mutect2, varscan2
- TOPORS | c.2956C>T p.P986S | Missense Mutation (SNP) | VAF 119/168 reads (71%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV62118454; called by muse, mutect2, varscan2
- TRPM2 | c.1801G>C p.G601R | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); catalogued as COSV55978300; called by muse, mutect2, varscan2
- TRPM8 | c.1355G>T p.R452L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.253); catalogued as rs200547297, COSV61222741, COSV61224767; called by muse, mutect2, varscan2
- TTN | c.24114G>A p.A8038= (on ENST00000591111; = p.A7111= on NM_133378.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 8/36 reads (22%) | catalogued as rs397517514, COSV60024067; ClinVar: likely benign; called by mutect2, varscan2
- UBXN4 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as COSV55638589; called by muse, mutect2, varscan2
- UGT8 | c.836G>T p.W279L | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as COSV60421544; called by muse, varscan2
- USP26 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs759613833, COSV63709575; called by muse, mutect2, varscan2
- USP33 | c.125T>G p.L42W | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1557862629, COSV62471778; called by muse, mutect2, varscan2
- USP34 | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 55/655 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.335); catalogued as rs796973508, COSV68407739; called by muse, mutect2
- USP42 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs752933903, COSV60358290; called by muse, mutect2, varscan2
- USP54 | c.3341G>T p.S1114I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV60448781; called by muse, mutect2, varscan2
- UTP6 | c.622-2A>C p.X208_splice | Splice Site (SNP) | VAF 42/91 reads (46%) | catalogued as COSV55576231; called by muse, mutect2, varscan2
- VCAN | c.9302G>T p.G3101V | Missense Mutation (SNP) | VAF 93/267 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54118395; called by muse, mutect2, varscan2
- VCAN | c.9941G>T p.R3314L | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763390705, COSV54110210, COSV54118403; called by muse, mutect2, varscan2
- WDR64 | c.1154C>A p.S385Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100844070, COSV63801182; called by muse, mutect2, varscan2
- XKR4 | c.977T>G p.V326G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV59342576; called by muse, mutect2, varscan2
- ZBED9 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.981); catalogued as COSV71729817; called by mutect2, varscan2
- ZEB2 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV57953820, COSV57967630; called by muse, mutect2, varscan2
- ZNF165 | c.412-1G>A p.X138_splice | Splice Site (SNP) | VAF 18/75 reads (24%) | catalogued as COSV66103059; called by muse, mutect2, varscan2
- ZNF318 | c.4849C>G p.P1617A | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV58938394; called by muse, mutect2, varscan2
- ZNF33A | c.1427C>A p.S476Y (on ENST00000458705 / NM_006974.3; = p.S477Y on NM_006954.2) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs1367238406, COSV56727475, COSV56728227; called by muse, varscan2
- ZNF33A | c.1489G>A p.E497K (on ENST00000458705 / NM_006974.3; = p.E498K on NM_006954.2) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.227); catalogued as COSV56728231; called by muse, varscan2
- ZNF37A | c.706A>T p.T236S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1448927248, COSV61075914; called by muse, varscan2
- ZNF432 | c.1690A>T p.T564S | Missense Mutation (SNP) | VAF 63/101 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV55418766; called by muse, mutect2, varscan2
- ZNF479 | c.1479C>A p.Y493* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV58644357; called by muse, mutect2, varscan2
- ZNF560 | c.1079C>A p.P360H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV56872247; called by muse, mutect2, varscan2
- ZNF609 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58591139; called by muse, mutect2
- ZNF621 | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV59459354; called by muse, mutect2, varscan2
- ZNF804A | c.343C>G p.Q115E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV56474495; called by muse, mutect2, varscan2
- ZNF804A | c.598G>T p.V200F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56474504; called by muse, varscan2
- ZNF804B | c.2805G>C p.K935N | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60822508, COSV60859475; called by muse, mutect2, varscan2
- ZNF81 | c.941A>G p.K314R | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV58578871; called by muse, varscan2
- ZNF831 | c.4453G>T p.D1485Y | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV64040273, COSV64045902; called by muse, mutect2, varscan2
- ZNF883 | c.274A>G p.T92A | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV71309287; called by muse, mutect2, varscan2
- ZNF91 | c.2030A>T p.K677M | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56094504; called by mutect2, varscan2
- ZNF91 | c.1106A>T p.K369M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV56094525; called by muse, varscan2
- ADGRE3 | c.1729del p.Q577Rfs*41 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | called by mutect2, pindel, varscan2
- CHRNB1 | c.1132_1147del p.S378Gfs*74 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- FASTKD1 | c.1138_1139del p.K380Dfs*20 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.206T>A p.L69H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT15 | c.36_38del p.F13del | In Frame Del (DEL) | VAF 23/98 reads (23%) | called by mutect2, pindel, varscan2
- LRRIQ1 | c.2443del p.A815Qfs*16 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- MAPT | c.2446del p.Q816Sfs*5 (on ENST00000262410 / NM_001377265.1; = p.Q424Sfs*5 on NM_005910.5) | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by pindel, varscan2
- MZF1 | c.41dup p.E15Rfs*3 | Frame Shift Ins (INS) | VAF 10/70 reads (14%) | called by mutect2, pindel
- NTSR2 | c.651_652delinsT p.L219Wfs*3 | Frame Shift Del (DEL) | VAF 48/228 reads (21%) | called by pindel, varscan2*
- RSPH1 | c.149del p.F50Sfs*93 | Frame Shift Del (DEL) | VAF 44/132 reads (33%) | called by mutect2, pindel, varscan2
- TDRD5 | c.2278del p.H760Ifs*43 | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | called by mutect2, pindel, varscan2
- TPTE | c.1036G>C p.G346R (on ENST00000618007 / NM_199261.4; = p.G328R on NM_199259.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VN1R5 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AC100868.1 | c.2034G>C p.L678= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV51850878; called by muse, mutect2, varscan2
- ADGRV1 | c.13074C>A p.L4358= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV67996679; called by muse, mutect2, varscan2
- AGPAT4 | c.183G>T p.L61= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV57251958; called by muse, varscan2
- ARID5A | c.1116G>A p.L372= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV62591666, COSV62591859; called by muse, mutect2, varscan2
- ARMC4 | c.2004A>T p.A668= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV59476042; called by muse, mutect2, varscan2
- ASTN1 | c.1393C>A p.R465= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV56077731, COSV56088517; called by muse, mutect2, varscan2
- BIRC6 | c.13107C>G p.L4369= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as COSV70207082; called by muse, mutect2, varscan2
- BMPER | c.855T>C p.C285= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as rs1433110161, COSV51833159; called by muse, mutect2, varscan2
- C2orf16 | c.663A>G p.L221= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV68647421; called by muse, mutect2, varscan2
- CECR2 | c.2433G>A p.K811= (on ENST00000342247 / NM_001290047.2; = p.K628= on NM_001290046.1) | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV52849512; called by muse, mutect2, varscan2
- CES1 | c.1119G>T p.L373= (on ENST00000361503 / NM_001025194.2; = p.L372= on NM_001266.5) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV62090795; called by muse, mutect2, varscan2
- CRY2 | c.804A>T p.T268= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV69889475; called by muse, mutect2, varscan2
- CTNND2 | c.2106G>A p.R702= | Silent (SNP) | VAF 48/114 reads (42%) | catalogued as COSV58933575; called by muse, mutect2, varscan2
- CTSV | c.873G>A p.S291= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs145877427; called by muse, mutect2, varscan2
- CUL9 | c.1722G>A p.L574= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV52735838; called by muse, mutect2, varscan2
- CUZD1 | c.1254G>A p.L418= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV59028415; called by muse, mutect2, varscan2
- ENPP1 | c.2373C>A p.V791= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV62936982; called by muse, varscan2
- FAM47C | c.2214C>T p.L738= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as rs1348688407, COSV63730956; called by muse, mutect2, varscan2
- FBN2 | c.7197C>G p.S2399= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV52548485; called by muse, mutect2
- FCGR2C | c.153G>T p.V51= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as COSV63442647; called by muse, mutect2, varscan2
- FLNC | c.3741G>A p.A1247= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs763047367, COSV57966400; called by muse, mutect2, varscan2
- GAS7 | c.1074G>A p.E358= (on ENST00000432992 / NM_201433.2; = p.E218= on NM_003644.3) | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as COSV60444710; called by muse, mutect2, varscan2
- GOLGA2 | c.1941G>A p.A647= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs772411440, COSV57856732; called by mutect2, varscan2
- GPM6A | c.150G>A p.A50= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs144181937; called by muse, mutect2, varscan2
- GREM1 | c.492T>A p.P164= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV55716576; called by muse, mutect2, varscan2
- GUSB | c.627C>T p.F209= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV59220758, COSV59222871; called by muse, mutect2, varscan2
- HFM1 | c.3612T>C p.S1204= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as COSV54038562; called by muse, mutect2, varscan2
- IL20 | c.213G>A p.L71= | Silent (SNP) | VAF 92/139 reads (66%) | catalogued as COSV65585236; called by muse, mutect2, varscan2
- IPMK | c.291C>T p.D97= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV64244757; called by muse, mutect2, varscan2
- ITK | c.63T>A p.T21= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV70065410; called by muse, mutect2, varscan2
- KRT20 | c.957C>A p.A319= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as COSV51426430; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.657C>T p.A219= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV53286987; called by muse, mutect2, varscan2
- LRRIQ3 | c.1155C>A p.I385= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs775246908, COSV63050886; called by muse, mutect2, varscan2
- MAGEB4 | c.108A>G p.E36= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV64397838; called by muse, mutect2, varscan2
- MCM8 | c.1740G>T p.G580= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV54520478; called by muse, mutect2, varscan2
- MET | c.1149G>T p.V383= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs1033586067, COSV59263681, COSV59270471; called by muse, mutect2, varscan2
- METTL18 | c.765A>G p.P255= | Silent (SNP) | VAF 43/119 reads (36%) | catalogued as COSV53683396; called by muse, mutect2, varscan2
- MROH2B | c.2748G>C p.L916= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV68190177; called by muse, mutect2
- MSX1 | c.882T>C p.H294= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV66947995; called by muse, varscan2
- MYO16 | c.795T>C p.Y265= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV51821576, COSV51822690; called by muse, mutect2
- NATD1 | c.207C>T p.I69= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV67541412; called by mutect2, varscan2
- NSUN2 | c.717C>G p.V239= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV52957525, COSV99243154; called by muse, mutect2, varscan2
- OARD1 | c.204G>T p.V68= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV55108643; called by muse, mutect2, varscan2
- OR10G8 | c.270T>C p.A90= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV70909551; called by muse, mutect2, varscan2
- OR2M5 | c.846T>C p.T282= | Silent (SNP) | VAF 45/91 reads (49%) | catalogued as rs1309690412, COSV63547188; called by muse, mutect2, varscan2
- OR4D5 | c.264C>T p.G88= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV58305727; called by muse, mutect2, varscan2
- OR4K5 | c.405C>A p.I135= | Silent (SNP) | VAF 34/199 reads (17%) | catalogued as rs1200618451, COSV60004864, COSV60005231; called by muse, mutect2, varscan2
- OR51F1 | c.225A>G p.L75= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs1182294140, COSV58581084; called by muse, mutect2, varscan2
- OR5P2 | c.333G>T p.L111= | Silent (SNP) | VAF 43/147 reads (29%) | catalogued as COSV61491388; called by muse, mutect2, varscan2
- PGGHG | c.945A>G p.P315= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV67141666; called by muse, mutect2, varscan2
- PIGQ | c.1953C>T p.G651= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs925606520, COSV99215896; called by muse, mutect2, varscan2
- PKD2L1 | c.1443C>A p.A481= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV58399384; called by muse, mutect2, varscan2
- PLD1 | c.981C>T p.I327= | Silent (SNP) | VAF 26/159 reads (16%) | catalogued as COSV60574989; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1128T>A p.A376= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV62613809; called by mutect2, varscan2
- PRRX2 | c.753G>T p.T251= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV65243541; called by muse, mutect2, varscan2
- RASEF | c.2010C>T p.V670= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV64589032; called by muse, mutect2, varscan2
- RELN | c.3351G>T p.L1117= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV59037689; called by muse, mutect2, varscan2
- RHAG | c.15C>T p.F5= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as rs776256535, COSV57706777; called by muse, mutect2, varscan2
- ROBO4 | c.672C>T p.S224= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV60628492; called by muse, mutect2, varscan2
- SCAPER | c.3691C>T p.L1231= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV57755585; called by muse, mutect2, varscan2
- SELE | c.1062G>A p.Q354= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs1454821766, COSV60978092; called by muse, mutect2, varscan2
- SELP | c.2271C>T p.T757= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs375732703, COSV55259457; called by muse, mutect2, varscan2
- SLC25A25 | c.1395C>A p.G465= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as COSV66087521; called by muse, mutect2, varscan2
- SMAD3 | c.261C>A p.I87= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV59290959; called by muse, mutect2, varscan2
- SNTB1 | c.603G>A p.V201= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs140148929, COSV67327495; called by muse, mutect2, varscan2
- SPEN | c.5169A>T p.S1723= | Silent (SNP) | VAF 76/147 reads (52%) | catalogued as COSV65368122; called by muse, mutect2, varscan2
- TKTL2 | c.1203C>T p.F401= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs756397639, COSV54921591; called by muse, mutect2, varscan2
- TTN | c.12250C>A p.R4084= (on ENST00000591111; = p.R4038= on NM_003319.4) | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV59867986, COSV60391908; called by muse, mutect2, varscan2
- VPS37A | c.856T>C p.L286= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV61366209; called by muse, mutect2, varscan2
- ZBTB46 | c.1155C>T p.A385= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs752573340, COSV55515648; called by muse, mutect2, varscan2
- ZNF99 | c.1992T>A p.L664= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV68057174; called by muse, varscan2
- AC074085.2 | n.185G>T | RNA (SNP) | VAF 15/34 reads (44%) | called by mutect2, varscan2
- AC244258.1 | n.387G>A | RNA (SNP) | VAF 27/175 reads (15%) | catalogued as rs1024771306; called by muse, mutect2, varscan2
- CTSL3P | n.292A>T | RNA (SNP) | VAF 29/86 reads (34%) | called by muse, mutect2, varscan2
- GABRA3 | c.-26-28917T>C | Intron (SNP) | VAF 6/13 reads (46%) | catalogued as COSV64806296; called by muse, mutect2, varscan2
- MORF4 | n.588T>A | RNA (SNP) | VAF 57/140 reads (41%) | called by muse, mutect2, varscan2
- POLR3D | chr8:22244987 C>T | 5'Flank (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1502G>T | 3'UTR (SNP) | VAF 16/79 reads (20%) | catalogued as COSV54687191, COSV99740739; called by muse, mutect2, varscan2
